CCDI case PBCGEB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/8d0257ad-baf4-41a1-88e6-a27d020429ed

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 14.9 years (5,452 days).

Biospecimens (3 samples)
- Sample 0DRO3J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRO3R: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRO3W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
